Somatic mutation profile of tumor specimen MP2PRT-PATBES-TMP1-A (aliquot MP2PRT-PATBES-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATBES, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,162 days).
Specimen MP2PRT-PATBES-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c482d721-e5b6-4b9b-9943-e41e81d77eb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBES-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBES-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ab6a28f-4aea-4763-8305-01863a2e71ee

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPB41L3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV104421719; called by muse, mutect2, varscan2
- PLBD1 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV53696047; called by muse, mutect2
- SGCB | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 24/371 reads (6%) | catalogued as rs750773622, CM080535, COSV67340578; called by muse, mutect2
- GPR6 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 210/528 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- HDGFL2 | c.698A>C p.D233A | Missense Mutation (SNP) | VAF 132/352 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- MAOA | c.885T>G p.I295M | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2
- ZNF799 | c.1671G>C p.E557D | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
